Somatic mutation profile of tumor specimen 0DOJW2 from CCDI case PBCCEF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mixed type rhabdomyosarcoma; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 5.8 years (2,129 days).
Specimen 0DOJW2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d81e2fba-992b-4cca-844e-e164abd4ab12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c43b6acd-b376-48a6-b299-60c3515e0e8a

The open-access MAF lists 75 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Intron 10, Silent 10, 3'UTR 4, 5'UTR 4, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 1583/4005 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- AK6 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 175/434 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146960635; called by muse, mutect2, varscan2
- AQP10 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 491/752 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs756699226; called by muse, mutect2, varscan2
- ARHGEF18 | c.1964C>T p.A655V (on ENST00000359920 / NM_001130955.2; = p.A551V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/784 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs150442510; called by muse, mutect2, varscan2
- ATP7A | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199888395, COSV58448727; called by muse, mutect2
- CDKN2C | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 295/694 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs771853517, COSV52954362, COSV52954434; called by muse, mutect2, varscan2
- CLTC | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 228/1169 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV52253696; called by muse, mutect2, varscan2
- CPB2 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 154/464 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV51674045; called by muse, mutect2
- DGLUCY | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 68/401 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs750915702; called by muse, mutect2, varscan2
- HAGH | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 162/405 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV68400976; called by muse, mutect2, varscan2
- JAKMIP3 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 242/489 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749027078, COSV53823033; called by muse, varscan2
- LRP1 | c.12406G>T p.V4136L | Missense Mutation (SNP) | VAF 251/814 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV99675092; called by muse, mutect2, varscan2
- MANEAL | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 195/427 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1307949157; called by muse, mutect2, varscan2
- MEN1 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as BM1426781, COSV53649639; called by muse, mutect2, varscan2
- NUDT10 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 288/696 reads (41%) | catalogued as COSV62854476; called by muse, varscan2
- PDAP1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 235/541 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99402847; called by muse, mutect2, varscan2
- PHEX | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 194/451 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV65075391; called by muse, mutect2, varscan2
- RCBTB2 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 180/441 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100749591; called by muse, mutect2, varscan2
- SH3GL2 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1256478484; called by muse, mutect2, varscan2
- SRPK3 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 50/762 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782397673; called by muse, mutect2
- ACAP3 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 315/635 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKDD1A | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP2B3 | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BICRA | c.4539G>T p.Q1513H | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CBLC | c.1196T>A p.V399E | Missense Mutation (SNP) | VAF 60/1136 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- COIL | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 251/1124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CPXM1 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 289/920 reads (31%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLEC1 | c.3392A>G p.K1131R | Missense Mutation (SNP) | VAF 69/864 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- DNAH11 | c.982+9_982+10del | Splice Region (DEL) | VAF 118/398 reads (30%) | called by pindel, varscan2
- DNAI3 | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 240/597 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELMO3 | c.1090C>A p.Q364K (on ENST00000652269; = p.Q311K on NM_024712.5) | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- GPRC5C | c.242A>G p.N81S (on ENST00000652232; = p.N36S on NM_018653.4) | Missense Mutation (SNP) | VAF 139/625 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LANCL3 | c.919del p.A307Lfs*27 | Frame Shift Del (DEL) | VAF 168/427 reads (39%) | called by mutect2, pindel, varscan2
- NLRP5 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 179/559 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NXF3 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PADI3 | c.1571A>C p.K524T | Missense Mutation (SNP) | VAF 154/360 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAOX | c.718_719del p.T240Cfs*4 | Frame Shift Del (DEL) | VAF 168/564 reads (30%) | called by pindel, varscan2
- PHTF1 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by mutect2, varscan2
- PMFBP1 | c.945A>C p.K315N | Missense Mutation (SNP) | VAF 167/401 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SALL3 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 132/295 reads (45%) | called by muse, mutect2, varscan2
- SOX5 | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 38/1272 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2
- SOX8 | c.352_354dup p.R118dup | In Frame Ins (INS) | VAF 173/453 reads (38%) | called by mutect2, pindel, varscan2
- TEX45 | c.821T>A p.V274E | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- USP37 | c.963T>G p.D321E | Missense Mutation (SNP) | VAF 202/1022 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZCCHC14 | c.1366G>T p.E456* (on ENST00000268616; = p.E593* on NM_015144.3) | Nonsense Mutation (SNP) | VAF 252/576 reads (44%) | called by muse, mutect2, varscan2
- ZNF529 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 159/616 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDX4 | c.405G>T p.S135= | Silent (SNP) | VAF 145/311 reads (47%) | catalogued as COSV65171867; called by muse, mutect2, varscan2
- CNOT1 | c.7122T>A p.G2374= | Silent (SNP) | VAF 161/345 reads (47%) | called by muse, mutect2, varscan2
- COASY | c.252A>G p.R84= | Silent (SNP) | VAF 284/582 reads (49%) | called by muse, mutect2, varscan2
- PCARE | c.1863G>A p.Q621= | Silent (SNP) | VAF 137/468 reads (29%) | called by muse, mutect2, varscan2
- RADIL | c.1119G>C p.R373= | Silent (SNP) | VAF 162/352 reads (46%) | called by muse, mutect2, varscan2
- RDM1 | c.603C>G p.A201= | Silent (SNP) | VAF 171/398 reads (43%) | called by muse, mutect2, varscan2
- SPAG9 | c.3459G>A p.V1153= (on ENST00000262013 / NM_001130528.3; = p.V1139= on NM_003971.6) | Silent (SNP) | VAF 98/1262 reads (8%) | called by muse, mutect2
- SPATA1 | c.411T>C p.N137= | Silent (SNP) | VAF 102/500 reads (20%) | catalogued as rs770275825; called by muse, mutect2, varscan2
- TACR3 | c.390C>G p.S130= | Silent (SNP) | VAF 289/644 reads (45%) | called by muse, mutect2, varscan2
- ZNF155 | c.849T>C p.T283= | Silent (SNP) | VAF 102/403 reads (25%) | called by muse, mutect2, varscan2
- ATAT1 | c.968+544G>C | Intron (SNP) | VAF 213/470 reads (45%) | catalogued as COSV104395178; called by muse, mutect2, varscan2
- BIN1 | c.*43C>T | 3'UTR (SNP) | VAF 97/350 reads (28%) | catalogued as rs1176652202; called by muse, mutect2, varscan2
- BIRC6 | c.11623+100C>G | Intron (SNP) | VAF 62/165 reads (38%) | called by muse, mutect2, varscan2
- BLID | c.-81T>G | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CATSPERG | c.-14-53G>T | Intron (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- CHID1 | c.*73_*85del | 3'UTR (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel, varscan2
- FMN2 | c.*61T>C | 3'UTR (SNP) | VAF 45/1234 reads (4%) | called by muse, mutect2
- H3-3B | c.-10-84G>A | Intron (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- MROH6 | c.*48C>T | 3'UTR (SNP) | VAF 66/437 reads (15%) | catalogued as rs890982340; called by muse, mutect2, varscan2
- MSR1 | c.1033+2551T>G | Intron (SNP) | VAF 80/1035 reads (8%) | called by muse, mutect2
- NAALADL1 | c.1416+57G>T | Intron (SNP) | VAF 71/208 reads (34%) | called by muse, mutect2, varscan2
- NNAT | c.-65A>G | 5'UTR (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- POU4F2 | c.-63G>T | 5'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2
- SH2D3C | chr9:127778682 G>C | 5'Flank (SNP) | VAF 124/199 reads (62%) | called by muse, mutect2, varscan2
- SNX22 | c.160-83C>G | Intron (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2
- SYTL2 | c.1387+60C>T | Intron (SNP) | VAF 118/368 reads (32%) | catalogued as rs745349170; called by muse, mutect2, varscan2
- TMEM59 | c.390+29G>T | Intron (SNP) | VAF 46/726 reads (6%) | called by muse, mutect2
- TPGS1 | c.338+55C>G | Intron (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- ZSWIM7 | c.-49G>A | 5'UTR (SNP) | VAF 125/261 reads (48%) | called by muse, mutect2, varscan2
